Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAD3, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAD3-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Right posterior sectionectomy

Organ: Liver (13.2 x 9.1 x 5.1 cm, 148.0 gm)

Lesion: Hepatic mass

Size: 5.0 x 4.2 x 3.9 cm

Cut surface: Encapsulated, pale tan, solid and lobulated mass

No necrosis and hemorrhage

Gross type: Multinodular confluent

Extent: Abuts but confined to the capsule

Resection margin: Not involved, grossly (safety margin: 1.5 cm)

Remaining parenchyme: Unremarkable, grossly

Representative sections are submitted.

Gross photo: Present

Blocks

T1-4 and TB, mass of liver x 5

RM, mass with resection margin x 1

L and NB, nontumorous liver parenchyme x 2

ICD-O-3
Carcinoma, hepatocellular NOS
Site Liver C22.0 8170/3
JW 5/19/14

MICROSCOPIC:

Tumor type: Hepatocellular carcinoma

Edmondson-Steiner grade

The worst: II

The major: II

Histologic type: Trabecular and tubular

Cell type: Hepatic

Fatty change: Yes

Cholangiocarcinoma: No

Fibrous capsule formation: No

Septum formation: No

Surgical resection margin invasion: No

Serosal invasion: Very close but free of tumor

Portal vein invasion: No

Vascular invasion: No

Bile duct invasion: No

Remaining liver parenchyme: Chronic hepatitis

Etiology: HBV

Grade, lobular: Mild

[page 2 of 2]
Grade, portoperiportal: Mild
Stage (fibrosis): Periportal
Cirrhosis: No

NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma
T56000, P10, M81703
DIAGNOSIS:
Liver, right, right posterior sectionectomy: Hepatocellular carcinoma
Suggestion :

Source: NCI Genomic Data Commons file 5fd0a615-c736-417a-b75a-26243a81c77b (TCGA-DD-AAD3.03056B3E-B81F-44C0-B21E-6C850D67DB43.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).